Somatic mutation profile of tumor specimen 0DE7FS from CCDI case PBBPLW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Myxopapillary ependymoma; Tissue or organ of origin: Cauda equina; Age at diagnosis: 11.3 years (4,117 days).
Specimen 0DE7FS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcb8b7b5-5af6-402c-ad90-8c5788a3f5d3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE7E5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05a4f402-dde3-48e9-b61d-159fc483ca36

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH3 | c.8734G>C p.E2912Q | Missense Mutation (SNP) | VAF 41/754 reads (5%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs1208269462; called by muse, mutect2
- GALNT9 | c.713C>G p.A238G | Missense Mutation (SNP) | VAF 224/872 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.071); catalogued as COSV61100960; called by muse, mutect2, varscan2
- KIAA1109 | c.3056G>A p.R1019Q | Missense Mutation (SNP) | VAF 169/412 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs367724763; called by muse, mutect2, varscan2
- PDS5B | c.3887C>T p.P1296L | Missense Mutation (SNP) | VAF 26/1104 reads (2%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.073); catalogued as COSV59726866; called by muse, mutect2
- ARHGAP39 | c.1837G>T p.E613* | Nonsense Mutation (SNP) | VAF 38/240 reads (16%) | called by muse, mutect2, varscan2
- CATSPERD | c.520T>C p.Y174H | Missense Mutation (SNP) | VAF 30/395 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRM8 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 120/602 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- ZNF207 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 57/241 reads (24%) | called by muse, mutect2, varscan2
- CDK8 | c.-18G>T | 5'UTR (SNP) | VAF 26/278 reads (9%) | called by muse, mutect2
- CLCN2 | c.1170+53C>G | Intron (SNP) | VAF 101/382 reads (26%) | called by muse, mutect2, varscan2
